Surgical pathology report (de-identified scan), TCGA case TCGA-QK-A6VC, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Emory University - Winship Cancer Inst., specimen TCGA-QK-A6VC-01A (Primary Tumor).

[page 1 of 6]
Document Type:
Document Date:
Document Status:
Document Title:
Performed By:
Verified By:
Encounter info:

Anat Path Reports

ICD-O-3
Carcinoma, squamous
cell NOS 8070/3
Site C&F
Hypopharynx NOS
path C13.9
Overlapping lesion of
lip, oral cavity & pharynx
C14.8
JH 8/2/13

*** Final Report ***

(Verified)

Patient Name:

MRN:

Location:

Client:

Submitting Phys:

Copy To Phys:

Acc #:

DOB:

Gender:

F

Collected:

Received:

Reported:

Final Surgical Pathology Report

Final Pathologic Diagnosis

- A. ESOPHAGEAL MARGIN, EXCISION, A1FS:
- SKELETAL MUSCLE AND FIBROUS CONNECTIVE TISSUE.
- NO SURFACE EPITHELIUM PRESENT.
- NEGATIVE FOR INVASIVE CARCINOMA.
- B. LEFT PHARYNX MARGIN, EXCISION, B1FS:
- SQUAMOUS MUCOSA, CHRONICALLY INFLAMED.
- NEGATIVE FOR HIGH-GRADE DYSPLASIA AND INVASIVE CARCINOMA.
- C. RIGHT MEDIAL PHARYNX MARGIN, EXCISION, C1FS:
- SQUAMOUS MUCOSA, CHRONICALLY INFLAMED.
- NEGATIVE FOR HIGH-GRADE DYSPLASIA AND INVASIVE CARCINOMA.
- D. RIGHT LATERAL PHARYNX MARGIN, EXCISION, D1FS:
- SQUAMOUS MUCOSA AND SKELETAL MUSCLE BUNDLES.
- NEGATIVE FOR HIGH-GRADE DYSPLASIA AND INVASIVE CARCINOMA.
- E. BASE OF TONGUE MARGIN, EXCISION, E1FS:
- SQUAMOUS MUCOSA WITH LYMPHOID AGGREGATES.
- NEGATIVE FOR HIGH-GRADE DYSPLASIA AND INVASIVE CARCINOMA.
- F. HYPOPHARYNX, RIGHT, TOTAL LARYNGOPHARYNGECTOMY/COMPLETE THYROIDECTOMY, F1FS:
- INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED (4.8 X 3.1 X 3.0 CM).
- CARCINOMA INVOLVES ESOPHAGUS, RIGHT THYROID GLAND, AND ABUTS ANTERIOR AND POSTERIOR ASPECT OF THYROID CARTILAGE.
- ALL MUCOSAL AND SOFT TISSUE MARGINS (INCLUDES PARTS A, B, C, D, E) NEGATIVE FOR CARCINOMA.
- PERINEURAL INVASION IDENTIFIED.
- THYROID:
- RIGHT: THYROID PARENCHYMA INVADDED BY SQUAMOUS CELL CARCINOMA.

[page 2 of 6]
- LEFT: THYROID PARENCHYMA, NEGATIVE FOR MALIGNANCY .
- INCIDENTAL PARATHYROID GLAND PARENCHYMA, LOCATED IN RIGHT SOFT TISSUES (F14).
- SEE SYNOPTIC REPORT AND COMMENT.

- G. LYMPH NODES, RIGHT LEVEL I, NECK DISSECTION:
- FIVE LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/5).
- SALIVARY GLAND PARENCHYMA WITH FOCAL CHRONIC INFLAMMATION.
- H. LYMPH NODES, RIGHT LEVEL II, III, IV, NECK DISSECTION:
- METASTATIC CARCINOMA POSITIVE IN ONE OF ELEVEN LYMPH NODES (1/11).
- FOCUS OF CARCINOMA MEASURES 1.5CM IN 1.8CM LYMPH NODE.
- I. LYMPH NODES, RIGHT LEVEL V, NECK DISSECTION:
- TWENTY-TWO LYMPH NODES NEGATIVE FOR CARCINOMA (0/22).
- J. LYMPH NODES, LEFT LEVEL II, NECK DISSECTION:
- TWELVE LYMPH NODES NEGATIVE FOR CARCINOMA (0/12).
- K. LYMPH NODES, LEFT LEVEL III, NECK DISSECTION:
- FOUR LYMPH NODES NEGATIVE FOR CARCINOMA (0/4).
- L. LYMPH NODES, LEFT LEVEL IV, NECK DISSECTION:
- NINE LYMPH NODES NEGATIVE FOR CARCINOMA (0/9).
- M. LYMPH NODES, LEFT LEVEL VI, NECK DISSECTION:
- FOUR LYMPH NODES NEGATIVE FOR CARCINOMA (0/4).

Comment

Sections of the thyroid and parathyroid glands (slides F12,13,14) were also reviewed by

and with

concurrence.

Electronically Signed by

Assisted by:

Synoptic Worksheet

F. Total laryngopharyngectomy:

Specimen:	Hypopharynx Other: Larynx, thyroid, portion of esophagus
Received:	Fresh
Procedure:	Resection, Laryngopharyngectomy Neck (lymph node) dissection: Right I-V and Left II, III, IV, VI Other: Total thyroidectomy
Specimen Size:	Greatest dimension: 8.0 cm Additional dimension: 7.0 cm Additional dimension: 4.5 cm
Specimen Laterality:	Right Midline
Tumor Site:	Hypopharynx, Piriform sinus Hypopharynx, Postcricoid Hypopharynx, Pharyngeal wall (posterior and/or lateral)
Tumor Laterality:	Right Midline
Tumor Focality:	Single focus
Tumor Size:	Greatest dimension: 4.8 cm

[page 3 of 6]
Tumor Description: Macroscopic Extent of Tumor: Histologic Type: Histologic Grade: Margins: Lymph-Vascular Invasion: Perineural Invasion: Lymph Nodes, Extranodal Extension: Pathologic Staging (pTNM): TNM Descriptors: Primary Tumor (pT): Hypopharynx: Regional Lymph Nodes (pN): Hypopharynx: Distant Metastasis (pM): Ancillary Studies: -----	Additional dimension: 3.1 cm Additional dimension: 3 cm Exophytic Endophytic Thyroid gland (right), lumen of esophagus, skeletal muscles lateral and anterior lateral to hypopharynx, right aryepiglottic fold. Squamous cell carcinoma, conventional G2: Moderately differentiated Margins uninvolved by invasive carcinoma Distance from closest margin: 1 Unit of measurement: mm Margin(s): Right lateral and posterior lateral soft tissue (taken from formalin fixed specimen) Margins uninvolved by carcinoma in situ (includes moderate and severe dysplasia) Not identified Present Not identified Not applicable pT4a: Moderately advanced local disease. Tumor invades thyroid/cricoid cartilage, hyoid bone, thyroid gland, or central compartment soft tissue pN1: Metastasis in a single ipsilateral lymph node, 3 cm or less in greatest dimension Number of regional lymph nodes examined: 67 Number of regional lymph nodes involved: 1 Size (greatest dimension) of the largest positive lymph node: 1.8 cm Not applicable Human papillomavirus associated carcinoma negative
---	---

Clinical History

Cancer of the hypopharynx, squamous cell carcinoma. Laryngopharyngectomy, neck dissection, pectoralis flap, possible ALT transfer. HIV positive.

Specimen(s) Received

A: Esophageal margin
B: Left pharynx margin
C: Right medial pharynx
D: Right lateral pharynx
E: Base of tongue
F: Total laryngopharyngectomy
G: Right level 1
H: Right level 2,3, 4, 4
I: Right level 5
J: Left level 2
K: Left level 3
L: Left level 4
M: Left level 6

Gross Description

Specimen A is received fresh for intraoperative consultation labeled with the patient's name, medical record number and entitled "esophageal margin." It consists of a single piece of soft tissue that measure 2.5 x 0.4 x 0.3 cm. The

[page 4 of 6]
specimen is submitted entirely for frozen section evaluation with the remaining tissue being submitted in cassette "A1FS." (Dictated by

Specimen B is received fresh for intraoperative consultation labeled with the patient's name, medical record number and entitled "left pharynx margin." It consists of a single piece of soft tissue that measure 2.8 x 0.3 x 0.2 cm. The specimen is submitted entirely for frozen section evaluation with the remaining tissue being submitted in cassette "B1FS." (Dictated by

Specimen C is received fresh for intraoperative consultation labeled with the patient's name, medical record number and entitled "right medial pharynx." It consists of a single piece of soft tissue that measure 2.5 x 0.3 x 0.2 cm. The specimen is submitted entirely for frozen section evaluation with the remaining tissue being submitted in cassette "C1FS." (Dictated by

Specimen D is received fresh for intraoperative consultation labeled with the patient's name, medical record number and entitled "right lateral pharynx." It consists of a small piece of soft tissue that measure 1.5 x 0.5 x 0.2 cm. The specimen is submitted entirely for frozen section evaluation with the remaining tissue being submitted in cassette "D1FS." (Dictated by

Specimen E is received fresh for intraoperative consultation labeled with the patient's name, medical record number and entitled "base of tongue." It consists of a single piece of soft tissue that measure 3.0 x 0.5 x 0.2 cm. The specimen is submitted entirely for frozen section evaluation with the remaining tissue being submitted in cassette "E1FS." (Dictated by

Specimen F is received fresh labeled with the patient's name, medical record number and entitled "total laryngopharyngectomy." It consists of a total laryngopharyngectomy specimen that measure 8.0 x 7.0 x 4.5 cm. It consists of a portion of larynx that is 8.0 x 3.0 x 2.5 cm and a portion of hypopharynx and esophagus that is approximately 7.5 cm in length and also possible left thyroid that is 3.0 x 2.0 x 1.0 cm in size and a possible right thyroid that is 3.5 x 2.5 x 1.0 cm. The right side of the specimen is inked black and the left is inked blue. In the hypopharynx there is a 4.8 x 3.1 x 3.0 cm white firm mass with areas of necrosis that involves the right aryepiglottic fold, hypopharyngeal mucosa with some ulceration and circumferentially surrounds the thyroid cartilage but does not appear to invade. Tumor appears to be 0.4 cm away from the mucosal lateral resection edge, 0.5 cm away from the right medial superior resection edge and 2.0 cm away from the left pharyngeal edge and 3.0 cm away from the inferior esophageal resection edge and 4.0 cm away from the tracheal resection margin. The cut edges of the esophagus are grossly free of tumor. Tumor appears to abut the right lateral and posterior-lateral soft tissue resection plane. It also appears to invade the right thyroid gland. It appears to be directly adjacent to the right upper portion of the larynx. Representative sections of the tumor and normal is submitted for Tumor Bank. Section of the tracheal resection margin was submitted en face for intraoperative consultation with the remaining tissue being submitted in cassette "F1FS." Gross photos are taken and are submitted as follows: Cassette summary is as follows. (Dictated by

Specimen G is received fresh for intraoperative consultation labeled with the patient's name, medical record number and entitled "right level 1." It consists of a single piece of soft tissue that measure 7.5 x 2.5 x 3.0 cm. The specimen consists of a large salivary gland that measure 5.0 x 3.5 x 1.5 cm. Cassette summary is as follows. (Dictated by

Specimen H is received in formalin labeled with the patient's name, medical record number and entitled "right levels 2, 3 and 4." The specimen consists of a single piece of soft tissue that measure 7.5 x 5.0 x 3.5 cm. The specimen consists of a portion of muscle that measure 5.5 x 5.0 x 1.0 cm. Cassette summary is as follows. (Dictated by

Specimen I is received fresh labeled with the patient's name, medical record number and entitled "right level 5." It consists of a single piece of soft tissue that measure 5.0 x 4.5 x 1.5 cm. Multiple lymph nodes are identified. The cassette summary is as follows. (Dictated by

Specimen J is received fresh labeled with the patient's name, medical record number and entitled "left level 2." It consists of a single piece of soft tissue that measures 4.0 x 2.0 x 1.0 cm. Multiple lymph nodes are identified. Cassette summary is as follows. (Dictated by

Specimen K is received fresh labeled with the patient's name, medical record number and entitled "left level 3." It consists of a single piece of soft tissue that measure 4.0 x 2.0 x 1.0 cm. Multiple lymph nodes are identified. Cassette summary is as follows. (Dictated by

[page 5 of 6]
Specimen L is received fresh labeled with the patient's name, medical record number and entitled "left level 4." It consists of a single piece of soft tissue that measure 3.0 x 2.0 x 2.0 cm. Multiple lymph nodes are identified. Cassette summary is as follows. (Dictated by

Specimen M is received fresh labeled with the patient's name, medical record number and entitled "left level 6." It consists of a single piece of soft tissue that measure 3.5 x 1.5 x 1.0 cm. Multiple lymph nodes are identified. Cassette summary is as follows. (Dictated by

CASSETTE SUMMARY:

F2:	Epiglottis
F3:	Left false and true vocal cords
F4:	Anterior commissure
F5:	Right true and false vocal cords
F6:	Representative portion of the right cartilage firm area (decalcified)
F7:	Representative section of tumor
F8:	Another section of right cartilage surrounded by necrotic tumor (decalcified)
F9:	Section of tumor in relation to lateral soft tissue margin, inked black
F10:	Perpendicular section of tumor in relation to the medial mucosal edge, black
F11:	Perpendicular section of lateral mucosal edge; edge inked black
F12:	Section of tumor and adjacent right thyroid
F13:	Left Thyroid
F14:	Section of right soft tissue
F15:	Additional sections of tumor in relationship to right lateral wall, inked black
F16:	Perpendicular section of right anterior soft tissue with margin inked black
F17:	Lesion protruding into lumen of esophagus
F18:	Perpendicular section of right posterior-lateral soft tissue with margin inked black
G1:	Four possible lymph nodes, submitted whole
G2:	Adipose tissue submitted for lymph node evaluation
G3:	Representative section of salivary gland
H1:	Representative muscular tissue
H2:	Grossly positive lymph node, 1.8 cm in greatest dimension
H3:	Single lymph node, bisected
H4:	Three possible lymph nodes, submitted whole
H5:	Three possible lymph nodes, submitted whole
H6:	Nodular portion of muscle
H7:	Adipose tissue submitted for lymph node evaluation
H8:	Single lymph node, bivalved
I1:	Four possible lymph nodes, submitted whole
I2:	Four possible lymph nodes, submitted whole
I3:	Single lymph node, greatest dimension are 2.5 cm, bivalved
I4:	Six possible lymph nodes
I5:	Four possible lymph nodes
I6:	Adipose tissue submitted for lymph node evaluation
J1:	Four possible lymph nodes, submitted whole
J2:	Three possible lymph nodes, submitted whole
J3:	Four possible lymph nodes
K1:	Single lymph node, bivalved
K2:	Single lymph node, bivalved
K3:	Single lymph node, bivalved
K4:	Adipose tissue submitted for lymph node evaluation
L1:	Single lymph node, bivalved
L2:	Single lymph node, bivalved
L3:	Four possible lymph nodes, submitted whole
L4:	Adipose tissue submitted for lymph node evaluation
M1:	Single lymph node, bivalved
M2, 3:	Remaining adipose tissue submitted for lymph node evaluation

Intraoperative Consult Diagnosis

[page 6 of 6]
A1FS: ESOPHAGEAL MARGIN (FROZEN SECTION): NEGATIVE FOR CARCINOMA AND HIGH GRADE DYSPLASIA.
B1FS: LEFT PHARYNX MARGIN (FROZEN SECTION): NEGATIVE FOR CARCINOMA AND HIGH GRADE DYSPLASIA.
C1FS: RIGHT MEDIAL PHARYNX (FROZEN SECTION): NEGATIVE FOR CARCINOMA AND HIGH GRADE DYSPLASIA.
D1FS: RIGHT LATERAL PHARYNX (FROZEN SECTION): NEGATIVE FOR CARCINOMA AND HIGH GRADE DYSPLASIA.
E1FS: BASE OF TONGUE (FROZEN SECTION): NEGATIVE FOR CARCINOMA AND HIGH GRADE DYSPLASIA.
F1FS: TRACHEAL MARGIN (FROZEN SECTION): NEGATIVE FOR CARCINOMA AND HIGH GRADE DYSPLASIA.

Frozen section results were communicated to the surgical team and were repeated back by
on at and the specimens were received at

Pathologist:

Microscopic Description

Microscopic examination performed.

Criteria	hw 7/22/13	Yes	No
IPSA Discrepancy			/
Site Malignancy History			/

Source: NCI Genomic Data Commons file 4ad580bf-a723-4698-81db-2291fcb1a36b (TCGA-QK-A6VC.BCD2B2DC-A45E-46BD-825A-4CE9FA305AA9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).